Somatic mutation profile of cancer-model specimen HCM-CSHL-0639-C56-85A (3D Organoid, passage 3; aliquot HCM-CSHL-0639-C56-85A-01D-A88G-36), derived from the primary tumor of HCMI case HCM-CSHL-0639-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenoma, borderline malignancy; Tissue or organ of origin: Ovary.
Specimen HCM-CSHL-0639-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc3c3f99-cf05-4b20-8920-905fcd580d66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0639-C56-11A (Solid Tissue Normal), aliquot HCM-CSHL-0639-C56-11A-11D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1adf8066-ebbb-4582-a9ea-93c7bcac8553

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1861A>C p.N621H (on ENST00000288602 / NM_001374244.1; = p.N581H on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 154/319 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs180177040, CM060878, COSV56062673, COSV56077649, COSV56286119; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 154/358 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- EIF1AX | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 135/281 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63309369; called by muse, mutect2, varscan2
- EIF4G3 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 199/451 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (1); catalogued as rs1160917662; called by muse, mutect2, varscan2
- LCN9 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52990578; called by muse, mutect2
- LRTM2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 257/544 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs201340302; called by muse, mutect2, varscan2
- MYO1A | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775862921; called by muse, mutect2, varscan2
- TAF1 | c.2736G>T p.W912C (on ENST00000373790 / NM_138923.4; = p.W933C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/543 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52111176; called by muse, mutect2
- TMED4 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 160/314 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs1448969318, COSV56941998; called by muse, mutect2, varscan2
- TNMD | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 256/562 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs188279671; called by muse, varscan2
- TTN | c.92512C>G p.R30838G (on ENST00000591111; = p.R23414G on NM_003319.4) | Missense Mutation (SNP) | VAF 209/411 reads (51%) | PolyPhen probably damaging (0.998); catalogued as COSV60090224; called by muse, mutect2, varscan2
- ZMYM3 | c.3827G>T p.R1276I | Missense Mutation (SNP) | VAF 185/424 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58737086; called by muse, mutect2, varscan2
- CARD11 | c.2877C>A p.S959R | Missense Mutation (SNP) | VAF 26/482 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- CSMD3 | c.8201C>T p.P2734L | Missense Mutation (SNP) | VAF 23/419 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2
- HYDIN | c.11905C>A p.L3969I | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LYN | c.386G>A p.W129* | Nonsense Mutation (SNP) | VAF 119/273 reads (44%) | called by muse, mutect2, varscan2
- MCMDC2 | c.1838T>C p.I613T | Missense Mutation (SNP) | VAF 123/289 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PACSIN1 | c.1160G>C p.G387A | Missense Mutation (SNP) | VAF 226/496 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PYCR1 | c.686A>T p.D229V | Missense Mutation (SNP) | VAF 214/514 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR1 | c.10132C>A p.Q3378K | Missense Mutation (SNP) | VAF 198/423 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC22A2 | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 129/295 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SMARCD2 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 353/696 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- SYNE2 | c.4517A>G p.N1506S | Missense Mutation (SNP) | VAF 165/345 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAF6L | c.1748C>G p.P583R | Missense Mutation (SNP) | VAF 356/740 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TBC1D8B | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATRX | c.1374A>G p.S458= | Silent (SNP) | VAF 254/490 reads (52%) | called by muse, mutect2, varscan2
- CCL15 | c.168C>T p.S56= | Silent (SNP) | VAF 22/628 reads (4%) | catalogued as rs1024740611; called by muse, mutect2
- CDH16 | c.996C>T p.N332= | Silent (SNP) | VAF 109/546 reads (20%) | catalogued as rs768163050, COSV55340036; called by muse, mutect2, varscan2
- CHTF8 | c.273C>A p.G91= | Silent (SNP) | VAF 19/563 reads (3%) | called by muse, mutect2
- FOXA1 | c.333C>T p.S111= | Silent (SNP) | VAF 46/924 reads (5%) | called by muse, mutect2
- GFPT1 | c.516C>T p.T172= | Silent (SNP) | VAF 27/387 reads (7%) | called by muse, mutect2
- GLI2 | c.765G>A p.S255= | Silent (SNP) | VAF 46/554 reads (8%) | catalogued as rs200901345, COSV58040532, COSV58046160; ClinVar: uncertain significance; called by muse, mutect2
- MT1HL1 | c.6C>T p.D2= | Silent (SNP) | VAF 280/601 reads (47%) | called by muse, mutect2, varscan2
- OR8D2 | c.40C>T p.L14= | Silent (SNP) | VAF 33/466 reads (7%) | catalogued as rs1053243161, COSV62488895; called by muse, mutect2
- PLEKHM1 | c.1653G>A p.K551= | Silent (SNP) | VAF 22/848 reads (3%) | called by muse, mutect2
- SETD2 | c.1950G>A p.K650= | Silent (SNP) | VAF 11/282 reads (4%) | called by muse, mutect2
- TECTA | c.552C>T p.Y184= | Silent (SNP) | VAF 195/411 reads (47%) | catalogued as rs148364865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM116 | c.-52C>G | 5'UTR (SNP) | VAF 108/239 reads (45%) | called by muse, mutect2, varscan2
